Somatic mutation profile of tumor specimen MMRF_2671_1_BM_CD138pos (aliquot MMRF_2671_1_BM_CD138pos_T1_KHS5U_L13790) from MMRF case MMRF_2671, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.2 years (15,781 days).
Specimen MMRF_2671_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c933d68-5022-4d48-9ac5-1f4f68410fb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2671_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2671_2_PB_WBC_C1_KHS5U_L13791; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8925e0f0-9c10-48bd-b915-05f5c3716528

The open-access MAF lists 124 somatic variants for this specimen: 50 protein-altering or splice-affecting, 16 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 26, Silent 16, Intron 14, 5'UTR 9, 5'Flank 4, 3'Flank 4, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 80/196 reads (41%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CASQ2 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs779225945; called by muse, mutect2, varscan2
- CHST15 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 211/415 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100655116; called by muse, mutect2, varscan2
- COL26A1 | c.1102A>G p.R368G (on ENST00000313669 / NM_001278563.3; = p.R366G on NM_133457.4) | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs747186717; called by muse, mutect2, varscan2
- COL6A1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs760815168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREB5 | c.162G>A p.M54I (on ENST00000357727 / NM_182898.4; = p.M47I on NM_004904.3) | Missense Mutation (SNP) | VAF 175/616 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.775); catalogued as rs764412503; called by muse, mutect2, varscan2
- CTTNBP2 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 189/319 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169774539; called by muse, mutect2, varscan2
- DTNA | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51996617; called by muse, mutect2, varscan2
- ELAPOR2 | c.1544T>C p.F515S (on ENST00000450689 / NM_001142749.3; = p.F348S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 222/340 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461620416; called by muse, mutect2
- ERC2 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 164/353 reads (46%) | catalogued as COSV55648655, COSV99891783; called by muse, mutect2, varscan2
- IGLV3-1 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 170/386 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369274122; called by muse, varscan2
- MYH1 | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 225/256 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs867955270, COSV56843055; called by muse, mutect2, varscan2
- MYO6 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.946); catalogued as rs372062341; called by muse, mutect2, varscan2
- NSD1 | c.1549C>G p.Q517E | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs1131692328, COSV61770998; called by muse, mutect2, varscan2
- OPRL1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 242/260 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760977529; called by muse, mutect2, varscan2
- OSBPL5 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 138/261 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs146107856; called by muse, mutect2, varscan2
- SHROOM3 | c.3830C>A p.S1277* | Nonsense Mutation (SNP) | VAF 108/513 reads (21%) | catalogued as COSV56040543; called by muse, mutect2, varscan2
- SIN3B | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs369206489; called by muse, mutect2, varscan2
- SOCS6 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs373205534; called by muse, mutect2, varscan2
- TRAPPC11 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs149339392; called by muse, mutect2, varscan2
- CHCHD10 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLSTN3 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CNTNAP5 | c.1181A>T p.Q394L | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- DSC3 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ELAPOR2 | c.1589T>C p.M530T (on ENST00000450689 / NM_001142749.3; = p.M363T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/316 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- FHOD3 | c.1269del p.T424Hfs*50 | Frame Shift Del (DEL) | VAF 41/381 reads (11%) | called by mutect2, pindel
- FP565260.1 | c.326+2T>C p.X109_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- FRYL | c.8695A>G p.T2899A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 97/106 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- IGLV3-1 | c.142dup p.D48Gfs*2 | Frame Shift Ins (INS) | VAF 176/469 reads (38%) | called by pindel, varscan2
- IL17B | c.45C>G p.I15M | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- IQCH | c.2861+3_2861+6del p.X954_splice | Splice Site (DEL) | VAF 42/173 reads (24%) | called by mutect2, pindel, varscan2
- KCNG1 | c.944C>A p.T315K | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, varscan2
- LAMA1 | c.7381C>G p.L2461V | Missense Mutation (SNP) | VAF 45/489 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.487); called by muse, mutect2
- LYST | c.889G>T p.G297W | Missense Mutation (SNP) | VAF 56/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTG1 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NF2 | c.1455C>A p.N485K | Missense Mutation (SNP) | VAF 99/397 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NLRC3 | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDILT | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PLA2G4A | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PLOD2 | c.1933-3C>T | Splice Region (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- RACK1 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAPGEF2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RERE | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- RFX8 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 139/370 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RPS6KL1 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SETD9 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1892T>A p.L631H (on ENST00000540229 / NM_001371097.1; = p.L570H on NM_001009562.4) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT5C | c.565dup p.D189Gfs*8 | Frame Shift Ins (INS) | VAF 126/325 reads (39%) | called by mutect2, pindel, varscan2
- TMEFF2 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 118/417 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- CDH16 | c.2403C>T p.L801= | Silent (SNP) | VAF 206/211 reads (98%) | called by muse, mutect2, varscan2
- CFAP69 | c.2181C>A p.G727= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as rs750396217; called by muse, mutect2, varscan2
- DAPK1 | c.3939G>A p.L1313= | Silent (SNP) | VAF 286/454 reads (63%) | called by muse, mutect2, varscan2
- DLGAP4 | c.1053G>A p.T351= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs1201358623; called by muse, mutect2, varscan2
- FLOT1 | c.792G>A p.Q264= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV100899814; called by muse, mutect2
- HUS1B | c.453C>T p.R151= | Silent (SNP) | VAF 85/192 reads (44%) | catalogued as rs568969254, COSV57864473; called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 194/210 reads (92%) | catalogued as rs367953381; called by muse, varscan2
- PPP4R1 | c.2247G>A p.V749= (on ENST00000400556 / NM_001042388.3; = p.V732= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/250 reads (20%) | called by muse, mutect2, varscan2
- PVR | c.892C>T p.L298= | Silent (SNP) | VAF 64/245 reads (26%) | called by muse, mutect2, varscan2
- RYR3 | c.1938C>A p.I646= | Silent (SNP) | VAF 98/220 reads (45%) | called by mutect2, varscan2
- SBF2 | c.1659C>T p.V553= | Silent (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- SCG2 | c.1560T>C p.N520= | Silent (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.4551G>A p.R1517= | Silent (SNP) | VAF 58/64 reads (91%) | catalogued as COSV100665485; called by muse, mutect2, varscan2
- SNX19 | c.2832A>G p.Q944= | Silent (SNP) | VAF 18/223 reads (8%) | called by muse, mutect2
- UBALD1 | c.117C>T p.F39= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as rs1385277615; called by muse, mutect2, varscan2
- ZIC3 | c.186G>A p.A62= | Silent (SNP) | VAF 91/98 reads (93%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-39022C>T | Intron (SNP) | VAF 155/271 reads (57%) | called by muse, mutect2, varscan2
- BRI3BP | c.*1513C>T | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- CACNA1E | c.*2403T>A | 3'UTR (SNP) | VAF 46/168 reads (27%) | called by muse, mutect2, varscan2
- CASP8 | c.306-1949T>C | Intron (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- CCAR1 | c.-51+178C>T | Intron (SNP) | VAF 31/56 reads (55%) | catalogued as rs948178619; called by muse, mutect2, varscan2
- CFAP94 | c.*102C>T | 3'UTR (SNP) | VAF 38/211 reads (18%) | catalogued as COSV100209371; called by muse, mutect2, varscan2
- CHRM2 | chr7:137016606 ins T | 3'Flank (INS) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- CPNE3 | c.*598A>G | 3'UTR (SNP) | VAF 87/183 reads (48%) | called by muse, mutect2, varscan2
- CYP1A1 | c.*904G>C | 3'UTR (SNP) | VAF 54/99 reads (55%) | called by muse, mutect2, varscan2
- DESI2 | c.*1237G>C | 3'UTR (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- DHX57 | c.*455A>C | 3'UTR (SNP) | VAF 40/80 reads (50%) | catalogued as rs1032843166; called by muse, varscan2
- DICER1 | c.*3912T>G | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by mutect2, varscan2
- DLGAP1 | c.*2110C>A | 3'UTR (SNP) | VAF 73/303 reads (24%) | called by muse, mutect2, varscan2
- DYRK1A | chr21:37513291 G>A | 3'Flank (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- DYRK1A | chr21:37513808 G>C | 3'Flank (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- ECHS1 | c.-16_-15del | 5'UTR (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.3300+34G>A | Intron (SNP) | VAF 77/167 reads (46%) | catalogued as rs749878529; called by muse, mutect2, varscan2
- EVC | c.*2104_*2149del | 3'UTR (DEL) | VAF 44/100 reads (44%) | called by mutect2, pindel
- FAM53C | c.*2276C>T | 3'UTR (SNP) | VAF 68/148 reads (46%) | called by muse, mutect2, varscan2
- GPIHBP1 | c.*474G>A | 3'UTR (SNP) | VAF 74/242 reads (31%) | catalogued as rs773478298, COSV58209533; called by muse, mutect2, varscan2
- HMGN1 | c.48+23_48+25dup | Intron (INS) | VAF 30/131 reads (23%) | catalogued as rs773459571; called by pindel, varscan2
- HNRNPA3 | c.-140T>A | 5'UTR (SNP) | VAF 29/54 reads (54%) | catalogued as rs1343964512; called by muse, mutect2, varscan2
- HSD17B7P2 | n.795A>G | RNA (SNP) | VAF 45/221 reads (20%) | called by muse, mutect2, varscan2
- IFT81 | c.1188+6072G>C | Intron (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- IGF1R | c.-519C>T | 5'UTR (SNP) | VAF 30/117 reads (26%) | called by muse, mutect2, varscan2
- IGLL5 | c.-26A>G | 5'UTR (SNP) | VAF 84/202 reads (42%) | called by muse, mutect2, varscan2
- IRF2 | c.87+219T>A | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- KRTCAP2 | c.4+30T>C | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- LMO1 | c.-164C>G | 5'UTR (SNP) | VAF 68/128 reads (53%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851315 C>T | 5'Flank (SNP) | VAF 225/234 reads (96%) | catalogued as rs537569481; called by muse, mutect2, varscan2
- MON2 | c.*326A>C | 3'UTR (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- MPV17 | chr2:27324592 G>A | 5'Flank (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- MSL2 | c.*570dup | 3'UTR (INS) | VAF 43/191 reads (23%) | catalogued as rs924817572; called by mutect2, varscan2
- MTCL1 | c.3561+2490C>T | Intron (SNP) | VAF 58/183 reads (32%) | called by muse, mutect2, varscan2
- MYO10 | c.*539G>A | 3'UTR (SNP) | VAF 68/328 reads (21%) | catalogued as rs1218805753; called by muse, mutect2, varscan2
- NAGPA | c.*289C>T | 3'UTR (SNP) | VAF 187/295 reads (63%) | called by muse, mutect2, varscan2
- NOX4 | c.*2324G>C | 3'UTR (SNP) | VAF 142/358 reads (40%) | called by muse, varscan2
- NUP214 | c.-119G>A | 5'UTR (SNP) | VAF 28/102 reads (27%) | catalogued as rs776002044; called by muse, varscan2
- OR5AS1 | c.-21G>A | 5'UTR (SNP) | VAF 46/202 reads (23%) | catalogued as rs766137120; called by muse, mutect2, varscan2
- PDCD6 | c.163+3653G>A | Intron (SNP) | VAF 113/532 reads (21%) | catalogued as rs1561029478; called by muse, mutect2, varscan2
- PGLYRP4 | c.-7C>T | 5'UTR (SNP) | VAF 50/470 reads (11%) | catalogued as rs369696338; called by muse, mutect2
- PITRM1 | chr10:3172829 C>T | 5'Flank (SNP) | VAF 33/509 reads (6%) | called by muse, mutect2
- PLEKHM1 | c.2901+99G>A | Intron (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- PSMD6 | c.352-154T>C | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- RAN | c.-240C>A | 5'UTR (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- RPS10 | c.*643G>A | 3'UTR (SNP) | VAF 38/420 reads (9%) | catalogued as COSV100402615; called by muse, mutect2
- RXFP3 | c.*124G>T | 3'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- SNORD116-3 | chr15:25059646 C>A | 3'Flank (SNP) | VAF 192/407 reads (47%) | called by mutect2, varscan2
- SOWAHC | c.*410dup | 3'UTR (INS) | VAF 40/104 reads (38%) | called by mutect2, varscan2
- SPRED2 | c.*1544G>C | 3'UTR (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- SPRING1 | c.*1573C>T | 3'UTR (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- SRSF7 | chr2:38751368 G>C | 5'Flank (SNP) | VAF 181/315 reads (57%) | catalogued as rs974119810, COSV57447288, COSV57448112; called by muse, mutect2, varscan2
- STAMBP | c.*929T>C | 3'UTR (SNP) | VAF 67/129 reads (52%) | called by muse, mutect2, varscan2
- TEDC1 | c.148-30C>T | Intron (SNP) | VAF 81/86 reads (94%) | catalogued as rs997328066; called by muse, mutect2, varscan2
- TMEM123 | c.*213C>A | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by mutect2, varscan2
- TMEM30A | c.*2435T>G | 3'UTR (SNP) | VAF 36/213 reads (17%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+214T>A | Intron (SNP) | VAF 78/93 reads (84%) | called by muse, varscan2
- UNKL | c.*2265C>T | 3'UTR (SNP) | VAF 59/185 reads (32%) | called by muse, mutect2, varscan2
